Surgical pathology report (de-identified scan), TCGA case TCGA-GD-A3OP, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site ABS - IUPUI, specimen TCGA-GD-A3OP-01A (Primary Tumor).

[page 1 of 3]
Operative Procedure:
Radical cystectomy

Specimen Received:

- A: Distal left ureter (FS)
- B: Distal right ureter (FS)
- C: Bladder and uterus, cervix, tubes and ovaries
- D: Tissue near uterus
- E: Right pelvic lymph nodes
- F: Left pelvic lymph nodes

Final Pathologic Diagnosis:

- A. Distal left ureter margin, excision for frozen section A:
Negative for tumor.
Frozen section diagnosis is confirmed.

- B. Distal right ureter margin, excision for frozen section B:
Negative for tumor.
Frozen section diagnosis is confirmed.

C. Urinary bladder, anterior exenteration:

Tumor histologic type: Urothelial carcinoma
Variant histology (%): Micropapillary carcinoma (90%) and
transitional cell carcinoma (5%)
Tumor size: 7.5 cm (greatest dimension)
Additional dimensions: 6.5 x 4 cm
Grade (WHO): High
Tumor configuration: Invasive
Associated epithelial lesions: None identified in sections examined
Microscopic tumor extension: Through the urinary bladder into the uterus
Lymph-vascular invasion: Present

Margins

Urethral: Negative

Ureteral: Negative

Paravesical soft tissue: focally positive

Other (specify): N/A

Additional pathologic findings: None

Paravesical lymph nodes: None identified

All lymph nodes: Metastatic carcinoma in situ present in four
lymph nodes (total number of pelvic lymph nodes = 5)
Size of largest lymph node metastasis: 1.5 cm

1CD-0-3

carcinoma, urothelial, NOS 8120/3
Site: bladder, wall, anterior C67-3

W 2/5/12

[page 2 of 3]
Part A is received fresh for frozen section evaluation additionally labeled "distal left ureter (FSA+X)" and consists of a segment of apparent ureter, having a length of 0.8 cm and a diameter that averages 0.6 cm. There is a suture at one pole and the opposing pole is shaved and submitted for frozen section evaluation (FSA) with residual frozen section tissue submitted in cassette A1 and remaining tissue is submitted entirely in cassette A2.

Part B is received fresh for frozen section evaluation additionally labeled "distal right ureter (FSB+X)" and consists of a segment of apparent ureter, having a length of 0.8 cm and an average diameter of 0.5 cm. There is a suture at one pole and the opposing pole is shaved and submitted for frozen section evaluation (FSB) with residual frozen section tissue submitted in cassette B1 and remaining tissue submitted entirely in cassette B2.

Part C is received in formalin additionally labeled "bladder and uterus, tubes, cervix and ovaries." This composite specimen has aggregate dimensions of 10.5 x 9 x 9 cm and consists of bladder with attached urethra, segment of bilateral ureters, uterine corpus with attached cervix and "vaginal patch," as well as bilateral adnexa and a moderate amount of perivesical fat. The specimen previously had its anterior aspect over inked in blue and the bladder has been opened for procurement of tissues. The posterior aspect is subsequently inked black. The bladder has dimensions of 4 x 4 x 4 cm to include an additional 1.5 cm in length of urethra. The uterine corpus is 3 cm in length by 3.8 x 2 cm with an additional attached 2.3 cm in length of cervix, which averages 2 cm in diameter. The "vaginal patch" has a length of 3.5 cm with additional width of 3 cm, 0.3 cm in thickness. The right ovary has dimensions of 2.5 x 1.5 x 0.8 cm with an overlying fimbriated fallopian tube, which is 5 cm in length and averages 0.8 cm in diameter. The left ovary is 2.5 x 2 x 1.1 cm with an overlying fimbriated fallopian tube, which is 5 cm in length and averages 0.6 cm in diameter. The surface of the uterine corpus is remarkable for an area of roughening, arising within the right cornu fundic aspect, which may represent site of removal of tissues (see part D). Upon further bisecting the specimen, the bladder is remarkable for diffuse thickening of the bladder wall, particularly notable on the posterior aspect with ulcerated urothelium particularly notable on the fundic aspect posterior wall with confluent extension involving the anterior aspect. This mass has extensive involvement of multiple structures with overall estimated dimensions of 7.5 x 6.5 cm with invasion into the uterine corpus/cervix for a depth of 4 cm and into the anterior superior aspect of the bladder for a depth of 2.5 cm (see also gross photos). This mass approaches to within 2.5 cm of the urethral margin of surgical resection. Both the left and right ureters are grossly probe patent with an average length of 6 cm, each which open into a markedly edematous trigone. This tumor abuts the perivesical fat adjacent to the left adnexa/uterine corpus. Additionally this tumor does approach the superior/posterior aspect of the bladder adjacent to the "bladder flap" site (see cassette C11). There is no gross evidence of tumor involvement of the surface of the vaginal patch or into the adnexal structures.

Sections are submitted as follows:

[page 3 of 3]
These lymph node candidates are submitted as follows:

F1-2 one whole lymph node bisected, one half in each cassette;

F3-4 one whole lymph node quadrisected, one half in each cassette.

Microscopic Description:

The final diagnosis of each specimen incorporates the microscopic examination findings.

END OF REPORT

Taken: DOB: (Age: Gender:

Source: NCI Genomic Data Commons file bc65100b-6b0b-4028-8d10-7e6c8a42b9cc (TCGA-GD-A3OP.6C700249-6A70-45C6-834B-DF271740FC33.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).